CCDI case PBCAXG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Retroperitoneum and peritoneum.
https://portal.gdc.cancer.gov/cases/951b6f18-ed00-418c-8a1b-41995e14ef4e

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Paraganglioma, NOS: ICD-O-3 morphology code: 8680/1; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 12.3 years (4,488 days).

Biospecimens (3 samples)
- Sample 0DOA25: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DOA2W: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DOA3O: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
